Somatic mutation profile of tumor specimen TCGA-BJ-A3EZ-01A (aliquot TCGA-BJ-A3EZ-01A-11D-A202-08) from TCGA case TCGA-BJ-A3EZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 51.7 years (18,882 days).
Specimen TCGA-BJ-A3EZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c0428de-2e18-49bc-9f86-095a597b712a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A3EZ-10A (Blood Derived Normal), aliquot TCGA-BJ-A3EZ-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72d1220c-517e-405f-a8f8-e074213dc000

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>C p.M1043I | Missense Mutation (SNP) | VAF 43/104 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as CM126698, COSV55873376, COSV55878974, COSV55898229; called by muse, mutect2, varscan2
- AOC1 | c.2081T>A p.F694Y | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62867901; called by muse, mutect2, varscan2
- ARRDC5 | c.1004C>T p.P335L (on ENST00000381781; = p.P321L on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV67787863; called by muse, mutect2, varscan2
- CAMK2A | c.1393G>A p.V465I (on ENST00000348628 / NM_171825.2; = p.V476I on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); catalogued as rs764264581, COSV62245867; called by muse, mutect2, varscan2
- CLIP2 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV56276809; called by muse, mutect2, varscan2
- DHX8 | c.2321-1G>A p.X774_splice | Splice Site (SNP) | VAF 46/138 reads (33%) | catalogued as COSV52252135; called by muse, mutect2, varscan2
- DNAH9 | c.9542C>T p.P3181L | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1342211438, COSV52344028, COSV52368742; called by muse, mutect2, varscan2
- FLII | c.3328G>A p.D1110N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV57497369; called by muse, mutect2, varscan2
- KATNIP | c.3547G>C p.E1183Q | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV55177416; called by muse, mutect2, varscan2
- LETM2 | c.1387G>T p.G463* (on ENST00000379957 / NM_001286819.2; = p.G368* on NM_144652.3) | Nonsense Mutation (SNP) | VAF 76/200 reads (38%) | catalogued as COSV52685833; called by muse, mutect2, varscan2
- MTMR12 | c.1878G>T p.L626F | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53783495; called by muse, mutect2, varscan2
- SRC | c.1521G>C p.E507D | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.949); catalogued as COSV62439592; called by muse, mutect2
- USP9Y | c.4586A>C p.Y1529S | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV59099075; called by muse, mutect2, varscan2
- UTP4 | c.1850A>G p.K617R | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs765477757, COSV58732456; called by muse, mutect2, varscan2
- ZNF48 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as rs145091254; called by muse, mutect2, varscan2
- LATS1 | c.261del p.F88Lfs*44 | Frame Shift Del (DEL) | VAF 41/199 reads (21%) | called by mutect2, pindel, varscan2
- ZNF337 | c.1367del p.E456Gfs*52 | Frame Shift Del (DEL) | VAF 82/233 reads (35%) | called by mutect2, pindel, varscan2
- ABL2 | c.948G>A p.V316= (on ENST00000502732 / NM_007314.4; = p.V301= on NM_005158.5) | Silent (SNP) | VAF 10/278 reads (4%) | catalogued as COSV61012517; called by muse, mutect2
- ADAM29 | c.441T>C p.H147= | Silent (SNP) | VAF 47/131 reads (36%) | catalogued as COSV63662376; called by muse, mutect2, varscan2
- ARHGEF15 | c.1329C>T p.F443= | Silent (SNP) | VAF 58/198 reads (29%) | catalogued as rs1466502908, COSV62724817, COSV62724859; called by muse, mutect2, varscan2
- INTS1 | c.63C>T p.H21= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV67177051; called by muse, mutect2, varscan2
- TMEM176B | c.510C>G p.V170= | Silent (SNP) | VAF 56/129 reads (43%) | catalogued as COSV58439194; called by muse, mutect2, varscan2
